Somatic mutation profile of tumor specimen TARGET-20-PARDDA-09A (aliquot TARGET-20-PARDDA-09A-01D) from TARGET case TARGET-20-PARDDA, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.6 years (4,593 days).
Specimen TARGET-20-PARDDA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f503bd84-4fd0-4a98-979c-d6e04cdcd9cf.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARDDA-14A (Bone Marrow Normal), aliquot TARGET-20-PARDDA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f4ad733-9898-451c-8786-0c49d882c1f9

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WT1 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 55/128 reads (43%) | catalogued as rs121907909, CM971596, COSV60066326; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GATA2 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM141458, COSV62002954; called by muse, mutect2, varscan2
- KIT | c.1256A>T p.D419V | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV55389804, COSV55416458; called by muse, varscan2
- KIT | c.1257C>G p.D419E | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- RAD21 | c.1221dup p.G408Rfs*5 | Frame Shift Ins (INS) | VAF 31/94 reads (33%) | called by mutect2, pindel, varscan2
- CACNA1F | c.5121G>A p.Q1707= | Silent (SNP) | VAF 11/16 reads (69%) | called by muse, mutect2, varscan2
- SALL1 | c.2928C>T p.H976= | Silent (SNP) | VAF 88/187 reads (47%) | catalogued as rs530363077, COSV51753746; called by muse, mutect2, varscan2
